MMRF case MMRF_1516 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/47bfb313-615e-4016-b85b-fea55adf5c35

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 83 years; Vital status: Dead; Days to death: 1,176 days (3.2 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 83.2 years (30,380 days); ISS stage: I; Days to last known disease status: 1,176 days (3.2 years); Days to last follow up: 1,176 days (3.2 years).
   Treatment given: Therapeutic agents: Lenalidomide + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,176.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 267 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.071 mg/dL; Immunoglobulin G 3.88 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 3.27 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.1 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 0.03 mg/dL.
- Day 94 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 4.06 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 5.34 mmol/L.
- Day 190: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.959 mg/dL; Immunoglobulin G 4.67 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 1.98 mmol/L; Albumin 34 g/L; Total Protein 5.9 g/dL; Glucose 5.17 mmol/L.
- Day 282: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 4.75 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.08 mmol/L; Glucose 5.5 mmol/L.
- Day 331 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.986 mg/dL; Immunoglobulin G 5.03 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.86 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 4.18 mmol/L.
- Day 457 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.943 mg/dL; Immunoglobulin G 5.53 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 5.5 g/dL; Glucose 4.62 mmol/L.
- Day 568 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 6.35 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.37 g/L; Beta 2 Microglobulin 2.71 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 6.77 mmol/L.
- Day 638 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 5.99 g/L; Immunoglobulin A 1.33 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 2.79 µg/mL; Lactate Dehydrogenase 2.12 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 5.8 g/dL; Glucose 7.37 mmol/L.
- Day 724 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.21 mg/dL; Immunoglobulin G 5.41 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.69 µg/mL; Lactate Dehydrogenase 1.9 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 81 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 4.18 mmol/L.
- Day 960 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 15.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.21 mg/dL; Immunoglobulin G 8.9 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.76 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.2 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -17: Weight: 64 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_1516_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_1516_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
